Somatic mutation profile of tumor specimen ALCH-ADFW-TTP1-A (aliquot ALCH-ADFW-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADFW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.3 years (26,758 days).
Specimen ALCH-ADFW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f7f751-6b40-4f55-8dc7-abfa8c8e5d67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADFW-NB1-A (Blood Derived Normal), aliquot ALCH-ADFW-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02a32690-65d8-4a92-8b3a-d20193738862

The open-access MAF lists 319 somatic variants for this specimen: 216 protein-altering or splice-affecting, 64 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 182, Silent 64, Intron 17, Nonsense Mutation 14, 3'UTR 9, Splice Site 8, Frame Shift Del 7, RNA 7, 5'UTR 5, Splice Region 4, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 332/1293 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OCRL | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 152/1093 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853260, CM981410, COSV63980092; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>C p.R248P | Missense Mutation (SNP) | VAF 102/412 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TTN | c.39358+1G>A p.X13120_splice (on ENST00000591111; = p.X5696_splice on NM_003319.4) | Splice Site (SNP) | VAF 126/799 reads (16%) | catalogued as rs771562210, CS1514673, COSV60268188; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACOX1 | c.629G>T p.R210L | Missense Mutation (SNP) | VAF 341/1569 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99503803; called by muse, mutect2, varscan2
- ACTRT1 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 64/330 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV64419666; called by muse, mutect2, varscan2
- ADAM7 | c.2202C>A p.F734L | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV51546567; called by muse, varscan2
- ADAMTS4 | c.1223G>A p.S408N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100917607; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>G p.A939G (on ENST00000506720 / NM_001322402.2; = p.A871G on NM_015236.6) | Missense Mutation (SNP) | VAF 85/330 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV101546801, COSV72230433; called by muse, mutect2, varscan2
- AMER3 | c.543del p.S183Afs*83 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | catalogued as COSV58467231; called by mutect2, pindel, varscan2
- ATM | c.2399C>G p.S800C | Missense Mutation (SNP) | VAF 198/1292 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV53732018; called by muse, mutect2, varscan2
- BICRAL | c.3042C>G p.I1014M | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV58408868; called by muse, mutect2, varscan2
- CEP135 | c.3259G>A p.A1087T | Missense Mutation (SNP) | VAF 142/711 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1168341025; called by muse, mutect2, varscan2
- CFAP91 | c.166G>C p.A56P | Missense Mutation (SNP) | VAF 64/568 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56344062; called by muse, mutect2, varscan2
- CNTNAP2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 158/954 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs771874359; called by muse, mutect2, varscan2
- COL11A1 | c.1616G>T p.R539I | Missense Mutation (SNP) | VAF 88/580 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV62175815, COSV62200353; called by muse, mutect2, varscan2
- CSMD3 | c.10227C>G p.H3409Q (on ENST00000297405 / NM_001363185.1; = p.H3240Q on NM_052900.3) | Missense Mutation (SNP) | VAF 70/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52349905; called by muse, mutect2, varscan2
- DAZL | c.513C>A p.Y171* | Nonsense Mutation (SNP) | VAF 25/554 reads (5%) | catalogued as COSV51712687; called by muse, mutect2
- DCLK1 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 36/472 reads (8%) | catalogued as COSV55212077, COSV55215398; called by muse, mutect2
- DMD | c.2083C>G p.L695V | Missense Mutation (SNP) | VAF 75/502 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as COSV55870343; called by muse, mutect2, varscan2
- DNAH9 | c.9170G>A p.R3057K | Missense Mutation (SNP) | VAF 120/582 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252607025; called by muse, mutect2, varscan2
- EFR3B | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 56/177 reads (32%) | catalogued as rs1357402522, COSV53119341, COSV53119706; called by muse, varscan2
- EML6 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 100/677 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1204679652; called by muse, mutect2, varscan2
- ERBB2 | c.3698C>T p.P1233L | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1427201404, COSV54079247; called by muse, mutect2, varscan2
- ERC2 | c.2512G>T p.A838S | Missense Mutation (SNP) | VAF 83/314 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs770603611; called by muse, mutect2, varscan2
- ESR2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 103/519 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016270637, COSV50829648; called by muse, mutect2, varscan2
- EYS | c.5078C>T p.S1693L | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58201654; called by muse, mutect2, varscan2
- EYS | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 121/596 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.015); catalogued as COSV61000782; called by muse, mutect2, varscan2
- FAM135B | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99417390; called by muse, mutect2, varscan2
- FAT3 | c.9566T>A p.L3189Q | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53123949; called by muse, mutect2, varscan2
- FRMD7 | c.1087T>C p.Y363H | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.687); catalogued as COSV53746183; called by muse, mutect2, varscan2
- FRS3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778007945; called by muse, mutect2, varscan2
- GABRG3 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 64/433 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61516563; called by muse, mutect2, varscan2
- GK5 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 36/911 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67486744; called by muse, mutect2
- GRM1 | c.3278C>T p.P1093L | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs765481825; called by mutect2, varscan2
- HTR4 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 54/1251 reads (4%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.779); catalogued as COSV58792603; called by muse, mutect2
- IL1RAPL1 | c.1624C>A p.P542T | Missense Mutation (SNP) | VAF 30/921 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV100150426; called by muse, mutect2
- IL6R | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 83/481 reads (17%) | catalogued as COSV59815107; called by muse, mutect2, varscan2
- ITIH6 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 77/404 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV54486411; called by muse, mutect2, varscan2
- KLK5 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100306998, COSV60451134; called by muse, mutect2, varscan2
- KRT73 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as rs750485971, COSV59838486; called by muse, mutect2, varscan2
- LRP1B | c.13196A>T p.Y4399F | Missense Mutation (SNP) | VAF 122/603 reads (20%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.489); catalogued as COSV101253879, COSV67237998; called by muse, mutect2, varscan2
- LRP1B | c.6925G>A p.E2309K | Missense Mutation (SNP) | VAF 112/494 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs1217576638, COSV67281725; called by muse, mutect2, varscan2
- LRRC28 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 29/179 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.085); catalogued as COSV100113461; called by muse, mutect2, varscan2
- MAP3K15 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 75/372 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs757135476, COSV58839274; called by muse, mutect2, varscan2
- MAP4K4 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 176/876 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1211624298; called by muse, mutect2, varscan2
- NISCH | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.912); catalogued as rs1274036569; called by muse, mutect2
- NPAP1 | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as rs1049156380, COSV61508665; called by muse, mutect2, varscan2
- NUP188 | c.2003T>A p.M668K | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs936689150; called by muse, mutect2, varscan2
- OBSCN | c.9446G>A p.R3149Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.069); catalogued as rs769573419, COSV52812052; called by muse, mutect2, varscan2
- OR10R2 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63769328; called by muse, mutect2
- OR10X1 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.239); catalogued as COSV63767313, COSV63767998; called by muse, mutect2, varscan2
- OR2T1 | c.491G>C p.S164T | Missense Mutation (SNP) | VAF 27/214 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.199); catalogued as COSV100822311, COSV63542705; called by muse, mutect2, varscan2
- OR8H3 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.019); catalogued as COSV57910577, COSV57911785; called by muse, mutect2, varscan2
- OTOGL | c.5653G>T p.D1885Y (on ENST00000547103; = p.D1876Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/394 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV54013856; called by muse, mutect2
- PBX1 | c.418G>C p.G140R | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as rs953834516; called by muse, mutect2, varscan2
- PCDHA1 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV65375149; called by muse, mutect2
- PKHD1 | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.035); catalogued as rs375547868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHH1 | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 52/356 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752855705; called by muse, mutect2, varscan2
- PPP2R3B | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs776968670, COSV66814381; called by muse, mutect2
- PTPRD | c.4705A>G p.M1569V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775086992; called by mutect2, varscan2
- PTPRZ1 | c.6584A>C p.D2195A | Missense Mutation (SNP) | VAF 56/511 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66447671; called by muse, mutect2, varscan2
- REV1 | c.388C>A p.Q130K | Missense Mutation (SNP) | VAF 34/830 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV51486977; called by muse, mutect2
- RPLP0 | c.374C>G p.A125G | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs777061954; called by muse, mutect2, varscan2
- SCNN1A | c.1629G>A p.T543= | Splice Region (SNP) | VAF 238/1195 reads (20%) | catalogued as rs1379832700; called by muse, mutect2, varscan2
- SEMA6C | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771054527; called by muse, mutect2, varscan2
- SETDB2 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 61/393 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1359231797, COSV51644964; called by muse, mutect2, varscan2
- SH3TC1 | c.3733A>G p.I1245V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs969450524; called by mutect2, varscan2
- SMAD9 | c.413-1G>A p.X138_splice | Splice Site (SNP) | VAF 109/499 reads (22%) | catalogued as rs753619705; called by muse, mutect2, varscan2
- SOGA3 | c.1479G>T p.M493I | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV100847008; called by muse, mutect2, varscan2
- STAG2 | c.3562G>T p.G1188* | Nonsense Mutation (SNP) | VAF 57/474 reads (12%) | catalogued as COSV99491965; called by muse, mutect2, varscan2
- TAB3 | c.245G>A p.S82N | Missense Mutation (SNP) | VAF 57/448 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.082); catalogued as COSV55838272; called by muse, mutect2, varscan2
- TARS1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 56/594 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs1368892669; called by muse, mutect2
- TECRL | c.774G>T p.L258= | Splice Region (SNP) | VAF 39/261 reads (15%) | catalogued as rs1378298597, COSV67085681; called by muse, mutect2, varscan2
- TMPRSS15 | c.2599C>A p.H867N | Missense Mutation (SNP) | VAF 193/821 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV53053292; called by muse, mutect2, varscan2
- UNC13A | c.2314G>T p.V772L | Missense Mutation (SNP) | VAF 94/370 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53205829; called by muse, mutect2, varscan2
- UPRT | c.323C>A p.A108E | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs1322803551, COSV64912748; called by muse, mutect2
- WDFY4 | c.3025C>A p.R1009S | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57438260; called by muse, mutect2, varscan2
- WDR7 | c.4447G>A p.G1483R | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484177630, COSV54358818; called by muse, mutect2, varscan2
- WNK2 | c.2680G>A p.V894M | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as rs746654332, COSV52941688; called by muse, mutect2, varscan2
- ZFP92 | c.723C>G p.C241W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100100244; called by muse, mutect2, varscan2
- ZIC1 | c.787G>T p.G263C | Missense Mutation (SNP) | VAF 51/264 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279059570; called by muse, mutect2, varscan2
- ZNF540 | c.534T>A p.H178Q | Missense Mutation (SNP) | VAF 60/800 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.187); catalogued as rs375850217; called by muse, mutect2
- ZNF540 | c.1376G>A p.R459K | Missense Mutation (SNP) | VAF 246/640 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV57111027; called by muse, mutect2, varscan2
- ZNF728 | c.305G>T p.R102I | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV101655257; called by muse, mutect2, varscan2
- ZNHIT1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.578); catalogued as rs1435416165, COSV56185864; called by muse, mutect2
- ZSCAN5B | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762169707; called by muse, mutect2
- ABCC3 | c.3523G>T p.D1175Y | Missense Mutation (SNP) | VAF 34/752 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- ADAM23 | c.2078+1G>A p.X693_splice | Splice Site (SNP) | VAF 45/317 reads (14%) | called by muse, mutect2, varscan2
- ADAM7 | c.2203C>A p.L735I | Missense Mutation (SNP) | VAF 48/278 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, varscan2
- ADGRG6 | c.3392G>C p.C1131S | Missense Mutation (SNP) | VAF 79/607 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRV1 | c.14024G>T p.G4675V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- AIFM1 | c.1573+5G>C | Splice Region (SNP) | VAF 85/652 reads (13%) | called by muse, mutect2, varscan2
- AKT3 | c.675G>T p.M225I | Missense Mutation (SNP) | VAF 85/674 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANAPC2 | c.60G>T p.L20F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ANXA11 | c.862del p.V288Lfs*8 | Frame Shift Del (DEL) | VAF 29/127 reads (23%) | called by mutect2, pindel, varscan2
- ASMT | c.979A>G p.R327G (on ENST00000381229; = p.R355G on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 215/1009 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASTN1 | c.2842G>T p.V948L | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BANP | c.1177-4A>T | Splice Region (SNP) | VAF 48/212 reads (23%) | called by muse, mutect2, varscan2
- BARD1 | c.1831G>T p.G611C | Missense Mutation (SNP) | VAF 161/960 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- BLMH | c.408del p.L136Ffs*3 | Frame Shift Del (DEL) | VAF 141/895 reads (16%) | called by mutect2, pindel, varscan2
- BRINP3 | c.1012A>T p.T338S | Missense Mutation (SNP) | VAF 78/442 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CA9 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 178/687 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CBWD1 | c.529-2A>C p.X177_splice | Splice Site (SNP) | VAF 238/938 reads (25%) | called by mutect2, varscan2
- CD200R1L | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2
- CDC14C | c.1013T>C p.I338T (on ENST00000428251; = p.I231T on NM_152627.3) | Missense Mutation (SNP) | VAF 102/654 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CHD2 | c.4907-2A>G p.X1636_splice | Splice Site (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2
- COP1 | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.058); called by muse, mutect2
- CSK | c.998T>G p.F333C | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CUL3 | c.287C>A p.S96* | Nonsense Mutation (SNP) | VAF 117/623 reads (19%) | called by muse, mutect2, varscan2
- CYFIP1 | c.992G>C p.R331P | Missense Mutation (SNP) | VAF 90/467 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DENND11 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, varscan2
- DHX37 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIAPH2 | c.1417T>A p.L473I | Missense Mutation (SNP) | VAF 108/511 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- EEFSEC | c.784A>C p.K262Q | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- EIF4G3 | c.482G>T p.G161V | Missense Mutation (SNP) | VAF 19/646 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- F8 | c.154A>T p.R52* | Nonsense Mutation (SNP) | VAF 172/1083 reads (16%) | called by muse, mutect2, varscan2
- FBXO30 | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 106/681 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FLNA | c.4552C>A p.P1518T | Missense Mutation (SNP) | VAF 83/431 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FLNA | c.3798G>T p.E1266D | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2
- FUOM | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 117/524 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FUT6 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 80/373 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- GABRB2 | c.218T>C p.M73T | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GJA10 | c.582C>A p.C194* | Nonsense Mutation (SNP) | VAF 91/387 reads (24%) | called by muse, mutect2, varscan2
- GJD2 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- GK | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 33/800 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.459); called by muse, mutect2
- GPX6 | c.88-2A>G p.X30_splice | Splice Site (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- GRHL2 | c.1872A>C p.E624D | Missense Mutation (SNP) | VAF 89/472 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY2C | c.2482A>G p.S828G | Missense Mutation (SNP) | VAF 44/296 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HEATR1 | c.3487A>G p.I1163V | Missense Mutation (SNP) | VAF 109/808 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- HSPH1 | c.529+1G>T p.X177_splice | Splice Site (SNP) | VAF 138/491 reads (28%) | called by muse, mutect2, varscan2
- HUS1B | c.302A>T p.K101M | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HUWE1 | c.8384G>A p.G2795D | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV3-35 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 14/402 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- IL9R | c.746G>T p.S249I | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.22); called by muse, mutect2
- ITGA4 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA9 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 62/844 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.401); called by muse, mutect2
- KCNA3 | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 54/339 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- KRT72 | c.1413C>A p.S471R | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2
- LRP1B | c.5030T>C p.V1677A | Missense Mutation (SNP) | VAF 118/727 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LRRC46 | c.464C>G p.T155R | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRRC49 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 91/575 reads (16%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- LUZP2 | c.56G>A p.S19N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- MARCHF11 | c.1117T>G p.L373V | Missense Mutation (SNP) | VAF 28/760 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.171); called by muse, mutect2
- MESP2 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMUT | c.1375G>A p.V459I | Missense Mutation (SNP) | VAF 170/1033 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- MPP6 | c.1534A>T p.N512Y | Missense Mutation (SNP) | VAF 133/753 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MRPL15 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 92/644 reads (14%) | called by muse, mutect2, varscan2
- MTREX | c.1678A>C p.N560H | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- MTUS2 | c.2141T>C p.M714T | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MUC21 | c.272C>A p.T91N | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- MYT1L | c.3278C>A p.T1093K | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYT1L | c.1987G>T p.V663L | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- NDST4 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- NEK3 | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- NPAS4 | c.1089C>A p.F363L | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- OR10D3 | c.532T>G p.F178V | Missense Mutation (SNP) | VAF 85/558 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR56A3 | c.183G>T p.Q61H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.396); called by muse, mutect2
- OR8J3 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PCDH11X | c.2797C>T p.P933S | Missense Mutation (SNP) | VAF 42/884 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- PDE4D | c.2080G>T p.A694S (on ENST00000340635 / NM_001104631.2; = p.A558S on NM_006203.4) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLEKHA6 | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2
- PLIN1 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- POLG | c.1412G>A p.C471Y | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- POLR1A | c.3473C>T p.S1158L | Missense Mutation (SNP) | VAF 276/1321 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- PPFIA2 | c.1272A>T p.E424D | Missense Mutation (SNP) | VAF 57/394 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PPP2R3A | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 38/895 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.399); called by muse, mutect2
- PRKG1 | c.698+1G>A p.X233_splice | Splice Site (SNP) | VAF 47/604 reads (8%) | called by muse, mutect2
- PTCHD1 | c.577G>T p.G193W | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PTCHD1 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAI1 | c.4643C>G p.T1548S | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RGPD4 | c.3255A>T p.L1085F | Missense Mutation (SNP) | VAF 342/1919 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- RUSF1 | c.1395G>C p.K465N | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SARDH | c.69G>T p.M23I | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); called by muse, mutect2
- SATB1 | c.959A>G p.Q320R | Missense Mutation (SNP) | VAF 62/310 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCAP | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SEPSECS | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 117/599 reads (20%) | called by muse, mutect2, varscan2
- SERPINA7 | c.239T>A p.L80H | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETD5 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 92/436 reads (21%) | called by muse, mutect2, varscan2
- SH3TC2 | c.1560G>T p.K520N | Missense Mutation (SNP) | VAF 110/527 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SLC22A12 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SLC6A8 | c.1037T>C p.L346P | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- SLITRK4 | c.2443A>T p.K815* | Nonsense Mutation (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- SMC2 | c.1780G>C p.A594P | Missense Mutation (SNP) | VAF 95/669 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX18 | c.248C>G p.S83W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- STAG2 | c.3563G>T p.G1188V | Missense Mutation (SNP) | VAF 55/461 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- TACSTD2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.352); called by mutect2, varscan2
- TBC1D23 | c.932A>G p.D311G | Missense Mutation (SNP) | VAF 107/903 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- TBC1D32 | c.2179G>T p.G727C | Missense Mutation (SNP) | VAF 127/1181 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TCF20 | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TEX13C | c.1014G>T p.K338N | Missense Mutation (SNP) | VAF 48/457 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- TGM1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- TMEM104 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2
- TRAF3 | c.1622C>G p.T541S | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAF3IP3 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 30/641 reads (5%) | called by muse, mutect2
- TRAV6 | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TRGV9 | c.290C>A p.T97K | Missense Mutation (SNP) | VAF 74/471 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TRIM64 | c.1066G>T p.V356F | Missense Mutation (SNP) | VAF 95/471 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USH2A | c.12818A>T p.Y4273F | Missense Mutation (SNP) | VAF 107/547 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP26 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 130/846 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- VSTM2B | c.853C>T p.H285Y | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.087); called by muse, mutect2
- WDFY4 | c.339del p.K114Sfs*28 | Frame Shift Del (DEL) | VAF 40/212 reads (19%) | called by mutect2, pindel, varscan2
- XRCC2 | c.338del p.G113Efs*21 | Frame Shift Del (DEL) | VAF 42/185 reads (23%) | called by mutect2, pindel, varscan2
- YLPM1 | c.3058del p.Y1020Tfs*17 | Frame Shift Del (DEL) | VAF 53/402 reads (13%) | called by mutect2, pindel, varscan2
- ZC4H2 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 50/390 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ZDHHC23 | c.640del p.S214Afs*69 | Frame Shift Del (DEL) | VAF 95/330 reads (29%) | called by mutect2, pindel*, varscan2
- ZNF107 | c.277A>T p.R93* | Nonsense Mutation (SNP) | VAF 46/264 reads (17%) | called by muse, mutect2, varscan2
- ZNF423 | c.638G>T p.R213L (on ENST00000563137 / NM_001379286.1; = p.R205L on NM_015069.4) | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF510 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 44/554 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2
- ZNF527 | c.1384A>G p.R462G | Missense Mutation (SNP) | VAF 82/870 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZNF571 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 44/1168 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.455); called by muse, mutect2
- ZNF677 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- ZNF724 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 111/610 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF729 | c.1426A>T p.T476S | Missense Mutation (SNP) | VAF 118/664 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZSCAN5C | c.1377G>T p.Q459H | Missense Mutation (SNP) | VAF 18/473 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ZXDA | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC068580.4 | c.927C>T p.R309= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as rs1174115566; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM1 | c.1254C>T p.I418= | Silent (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- ADAMTS16 | c.699G>C p.L233= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs764937722, COSV56999378; called by muse, mutect2, varscan2
- AMELX | c.330T>A p.T110= | Silent (SNP) | VAF 88/477 reads (18%) | called by muse, mutect2, varscan2
- APOB | c.9177T>C p.R3059= | Silent (SNP) | VAF 86/546 reads (16%) | called by muse, mutect2, varscan2
- ARID1B | c.6228C>T p.L2076= | Silent (SNP) | VAF 46/538 reads (9%) | catalogued as COSV99269985; called by muse, mutect2
- ARMC3 | c.1833T>C p.S611= | Silent (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- ASXL3 | c.4134G>T p.G1378= | Silent (SNP) | VAF 65/310 reads (21%) | called by muse, mutect2, varscan2
- ATF7IP | c.51G>T p.T17= | Silent (SNP) | VAF 104/486 reads (21%) | catalogued as COSV53769734, COSV53776327; called by muse, mutect2, varscan2
- BEND2 | c.1476T>C p.H492= | Silent (SNP) | VAF 152/771 reads (20%) | called by muse, mutect2, varscan2
- CAPN14 | c.1032G>T p.A344= | Silent (SNP) | VAF 61/379 reads (16%) | called by muse, mutect2, varscan2
- CCDC85A | c.921G>A p.K307= | Silent (SNP) | VAF 52/159 reads (33%) | called by muse, mutect2, varscan2
- CD109 | c.1554T>C p.S518= | Silent (SNP) | VAF 98/939 reads (10%) | catalogued as rs1315499752; called by muse, mutect2, varscan2
- CDH7 | c.2007T>A p.A669= | Silent (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- CFAP46 | c.3687T>C p.H1229= | Silent (SNP) | VAF 51/197 reads (26%) | catalogued as rs951305148; called by muse, mutect2, varscan2
- DCHS1 | c.6534C>A p.A2178= | Silent (SNP) | VAF 28/189 reads (15%) | called by muse, mutect2, varscan2
- DHX29 | c.3468T>C p.S1156= | Silent (SNP) | VAF 93/586 reads (16%) | called by muse, mutect2, varscan2
- EDIL3 | c.612G>A p.A204= | Silent (SNP) | VAF 40/268 reads (15%) | catalogued as rs757759194, COSV99677957; called by muse, mutect2, varscan2
- EGFR | c.402G>A p.E134= | Silent (SNP) | VAF 166/806 reads (21%) | called by muse, mutect2, varscan2
- ERICH3 | c.4362C>A p.G1454= | Silent (SNP) | VAF 34/107 reads (32%) | called by muse, mutect2, varscan2
- EVX1 | c.132C>T p.P44= | Silent (SNP) | VAF 17/120 reads (14%) | called by muse, mutect2, varscan2
- FAM120A | c.2724T>C p.R908= | Silent (SNP) | VAF 11/279 reads (4%) | called by muse, mutect2
- FAT3 | c.4407T>A p.I1469= | Silent (SNP) | VAF 31/535 reads (6%) | called by muse, mutect2
- FBXW5 | c.936G>A p.G312= | Silent (SNP) | VAF 25/125 reads (20%) | catalogued as rs1352800736; called by muse, mutect2, varscan2
- FCAR | c.291C>A p.R97= | Silent (SNP) | VAF 93/466 reads (20%) | called by muse, mutect2, varscan2
- GINS1 | c.459A>G p.L153= | Silent (SNP) | VAF 179/613 reads (29%) | called by muse, mutect2, varscan2
- H2BW2 | c.399C>G p.A133= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99685759; called by muse, mutect2, varscan2
- HEG1 | c.2403G>T p.L801= | Silent (SNP) | VAF 24/684 reads (4%) | called by muse, mutect2
- HEPHL1 | c.942C>T p.I314= | Silent (SNP) | VAF 87/580 reads (15%) | called by muse, mutect2, varscan2
- IGHV4-31 | c.339G>T p.V113= | Silent (SNP) | VAF 119/520 reads (23%) | catalogued as rs1390117663, rs752408878; called by mutect2, varscan2
- KCNQ2 | c.2355C>T p.D785= (on ENST00000359125 / NM_172107.4; = p.D757= on NM_004518.6) | Silent (SNP) | VAF 18/105 reads (17%) | called by muse, mutect2, varscan2
- LMF2 | c.1474C>A p.R492= | Silent (SNP) | VAF 13/119 reads (11%) | called by muse, mutect2, varscan2
- MAP3K19 | c.1602T>C p.H534= | Silent (SNP) | VAF 75/366 reads (20%) | called by muse, mutect2, varscan2
- MPPED1 | c.261A>T p.P87= | Silent (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- MS4A10 | c.246C>T p.V82= | Silent (SNP) | VAF 42/316 reads (13%) | called by muse, mutect2, varscan2
- MUC12 | c.11043C>A p.T3681= (on ENST00000379442; = p.T3538= on NM_001164462.1) | Silent (SNP) | VAF 215/1215 reads (18%) | catalogued as rs1167513113; called by muse, mutect2, varscan2
- MXRA5 | c.1740C>T p.A580= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs758750927; called by muse, mutect2, varscan2
- MYLK | c.972A>T p.S324= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- PCDHA6 | c.1647G>A p.V549= | Silent (SNP) | VAF 79/315 reads (25%) | called by muse, mutect2, varscan2
- PDZD2 | c.1401G>A p.Q467= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs1161605964; called by muse, mutect2, varscan2
- PHF12 | c.1185A>C p.A395= | Silent (SNP) | VAF 39/216 reads (18%) | catalogued as COSV52021531; called by muse, mutect2, varscan2
- PPFIA3 | c.957C>T p.A319= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- PRTG | c.1356T>C p.Y452= | Silent (SNP) | VAF 39/296 reads (13%) | called by muse, mutect2, varscan2
- RBM14 | c.1884G>A p.P628= | Silent (SNP) | VAF 59/475 reads (12%) | catalogued as rs767025849; called by muse, mutect2, varscan2
- RFX6 | c.1128G>A p.V376= | Silent (SNP) | VAF 208/1039 reads (20%) | catalogued as rs764900976; called by muse, mutect2, varscan2
- RGN | c.810G>A p.E270= | Silent (SNP) | VAF 41/310 reads (13%) | called by muse, mutect2, varscan2
- ROS1 | c.6606C>A p.P2202= | Silent (SNP) | VAF 50/568 reads (9%) | called by muse, mutect2
- RTF1 | c.618A>G p.Q206= | Silent (SNP) | VAF 111/607 reads (18%) | called by muse, mutect2, varscan2
- SEPSECS | c.225G>A p.R75= | Silent (SNP) | VAF 36/988 reads (4%) | called by muse, mutect2
- SFPQ | c.1260T>G p.S420= | Silent (SNP) | VAF 128/474 reads (27%) | catalogued as COSV61758462; called by muse, mutect2, varscan2
- SLC22A8 | c.939C>A p.T313= | Silent (SNP) | VAF 41/242 reads (17%) | called by muse, mutect2, varscan2
- STK38L | c.1158C>T p.V386= | Silent (SNP) | VAF 67/519 reads (13%) | catalogued as rs1168890569; called by muse, mutect2, varscan2
- TACSTD2 | c.150C>T p.G50= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs761587316; called by mutect2, varscan2
- TAS2R30 | c.177C>G p.L59= | Silent (SNP) | VAF 98/577 reads (17%) | called by muse, varscan2
- TEKT2 | c.201G>A p.R67= | Silent (SNP) | VAF 261/919 reads (28%) | called by muse, mutect2, varscan2
- TMC6 | c.1965G>T p.L655= | Silent (SNP) | VAF 33/319 reads (10%) | called by muse, mutect2, varscan2
- TMEM225 | c.186C>T p.D62= | Silent (SNP) | VAF 29/234 reads (12%) | called by muse, mutect2, varscan2
- TRIM64C | c.723C>T p.D241= | Silent (SNP) | VAF 40/398 reads (10%) | catalogued as rs555189322; called by muse, mutect2, varscan2
- TRIP11 | c.3810G>T p.L1270= | Silent (SNP) | VAF 232/1563 reads (15%) | called by muse, mutect2, varscan2
- UBP1 | c.1167C>T p.F389= | Silent (SNP) | VAF 89/358 reads (25%) | catalogued as rs1489625308; called by muse, mutect2, varscan2
- VWA1 | c.1110G>T p.P370= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- YY1 | c.819C>G p.P273= | Silent (SNP) | VAF 38/850 reads (4%) | called by muse, mutect2
- ZBTB40 | c.273C>G p.S91= | Silent (SNP) | VAF 52/1288 reads (4%) | called by muse, mutect2
- ZZEF1 | c.6882G>A p.K2294= | Silent (SNP) | VAF 100/356 reads (28%) | called by muse, mutect2, varscan2
- AC104472.1 | n.154T>G | RNA (SNP) | VAF 107/855 reads (13%) | called by muse, mutect2, varscan2
- AK4 | c.*1C>G | 3'UTR (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2
- ALDH1L1 | c.858+66G>A | Intron (SNP) | VAF 86/547 reads (16%) | catalogued as rs1182594476; called by muse, mutect2, varscan2
- AOAH | c.*84C>T | 3'UTR (SNP) | VAF 92/503 reads (18%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1038+23C>A | Intron (SNP) | VAF 59/364 reads (16%) | called by muse, mutect2, varscan2
- BMP1 | c.2107+1878G>T | Intron (SNP) | VAF 20/89 reads (22%) | called by muse, mutect2, varscan2
- CHM | c.1245-2454T>G | Intron (SNP) | VAF 76/661 reads (11%) | called by muse, mutect2, varscan2
- CUX1 | c.1384-46G>C | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- DKC1 | c.1259+113C>G | Intron (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- EFL1P1 | n.1694C>T | RNA (SNP) | VAF 21/189 reads (11%) | called by muse, mutect2, varscan2
- FAM183BP | n.611G>T | RNA (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- FBXO7 | c.967+12A>C | Intron (SNP) | VAF 147/1066 reads (14%) | called by muse, varscan2
- FKBP11 | c.388+773C>T | Intron (SNP) | VAF 30/191 reads (16%) | catalogued as rs772090140; called by muse, mutect2, varscan2
- FMR1 | c.*726G>A | 3'UTR (SNP) | VAF 91/587 reads (16%) | called by muse, mutect2, varscan2
- GBE1 | c.1934+33C>G | Intron (SNP) | VAF 13/350 reads (4%) | called by muse, mutect2
- HTR2C | c.-79-11576C>T | Intron (SNP) | VAF 23/740 reads (3%) | catalogued as rs868966419, COSV99347717; called by muse, mutect2
- INSC | c.1611+1100G>T | Intron (SNP) | VAF 78/822 reads (9%) | called by muse, mutect2
- KCNK2 | c.-117C>G | 5'UTR (SNP) | VAF 31/311 reads (10%) | catalogued as rs767708308, COSV67211890; called by muse, mutect2, varscan2
- MAGT1 | c.-4G>C | 5'UTR (SNP) | VAF 35/352 reads (10%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+757G>A | Intron (SNP) | VAF 31/522 reads (6%) | catalogued as rs1216877779; called by muse, mutect2
- MATN1 | c.*22C>A | 3'UTR (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- MED28 | c.*1866C>T | 3'UTR (SNP) | VAF 32/350 reads (9%) | catalogued as rs1341414140; called by muse, mutect2
- METAP1D | c.*6C>T | 3'UTR (SNP) | VAF 86/327 reads (26%) | called by muse, mutect2, varscan2
- NAA60 | c.*31C>A | 3'UTR (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- NHSL2 | c.-330C>T | 5'UTR (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- OR7D1P | n.611C>A | RNA (SNP) | VAF 28/538 reads (5%) | called by muse, mutect2
- POLE | c.-6G>C | 5'UTR (SNP) | VAF 14/85 reads (16%) | catalogued as rs534524789; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTN1 | c.1766-23031C>T | Intron (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- SCML2P1 | chr18:6928460 G>C | 3'Flank (SNP) | VAF 22/538 reads (4%) | called by muse, mutect2
- SHROOM4 | c.*9G>T | 3'UTR (SNP) | VAF 128/859 reads (15%) | called by muse, mutect2, varscan2
- SLC4A10 | c.49-62167C>A | Intron (SNP) | VAF 73/586 reads (12%) | catalogued as COSV99762875; called by muse, mutect2, varscan2
- SLC4A4 | c.1903+87C>T | Intron (SNP) | VAF 107/504 reads (21%) | catalogued as COSV52622668; called by muse, mutect2, varscan2
- SMPD1 | c.-17G>T | 5'UTR (SNP) | VAF 12/116 reads (10%) | catalogued as rs757482767; called by mutect2, varscan2
- TBC1D32 | c.*462G>C | 3'UTR (SNP) | VAF 11/146 reads (8%) | catalogued as rs955316721; called by muse, mutect2
- TCP10L3 | n.125G>A | RNA (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.34354+560C>A | Intron (SNP) | VAF 148/1365 reads (11%) | called by muse, mutect2, varscan2
- TUBB7P | n.257G>T | RNA (SNP) | VAF 70/260 reads (27%) | called by muse, mutect2, varscan2
- ZNF3 | c.145-95A>T | Intron (SNP) | VAF 107/446 reads (24%) | called by muse, mutect2, varscan2
- ZNF300P1 | n.1318G>C | RNA (SNP) | VAF 13/310 reads (4%) | called by muse, mutect2
